Somatic mutation profile of tumor specimen TCGA-QK-A6VC-01A (aliquot TCGA-QK-A6VC-01A-23D-A34J-08) from TCGA case TCGA-QK-A6VC, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Hypopharynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 62.6 years (22,865 days).
Specimen TCGA-QK-A6VC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4f71fb84-d7a9-471e-8ae4-c7ac3d3c1873.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QK-A6VC-10B (Blood Derived Normal), aliquot TCGA-QK-A6VC-10B-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1c9f61fa-9f70-4a1c-83a9-bd2d4c0e36d3

The open-access MAF lists 195 somatic variants for this specimen: 151 protein-altering or splice-affecting, 41 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 142, Silent 41, Nonsense Mutation 7, 5'Flank 1, Splice Region 1, Splice Site 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.430C>T p.Q144* | Nonsense Mutation (SNP) | VAF 15/64 reads (23%) | hotspot (GDC flag); catalogued as rs757274881, CM102352, COSV52662339, COSV52764890, COSV53424649; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABT1 | c.170T>A p.F57Y | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as COSV99223110; called by muse, varscan2
- ACTR1B | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV100007965, COSV100008031; called by muse, mutect2, varscan2
- ADAMTS3 | c.3332G>A p.G1111D | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV99710261; called by muse, mutect2, varscan2
- ADIG | c.140A>T p.D47V | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV100972524; called by muse, mutect2, varscan2
- AKAP6 | c.1754C>G p.S585C | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV99798444; called by muse, mutect2, varscan2
- AL645922.1 | c.583C>G p.L195V | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV100190662; called by muse, mutect2
- ANKRD13C | c.283C>G p.L95V | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.027); catalogued as rs773349689, COSV52029183, COSV52034652; called by muse, mutect2, varscan2
- AQR | c.3346G>C p.E1116Q | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99333250; called by muse, mutect2
- ASXL3 | c.1171G>T p.G391C | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.023); catalogued as COSV99323499; called by muse, mutect2, varscan2
- ATG2B | c.4705C>T p.P1569S | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV55890424; called by muse, mutect2, varscan2
- AVPR1A | c.1126G>C p.E376Q | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT tolerated (0.8); PolyPhen benign (0.062); catalogued as COSV100146771; called by muse, mutect2, varscan2
- BCAS1 | c.530C>A p.T177K | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV101006024; called by muse, mutect2
- BTC | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as COSV101201470; called by muse, mutect2, varscan2
- C9orf135 | c.503C>A p.P168Q | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV101019714; called by muse, mutect2, varscan2
- CALM3 | c.82A>G p.I28V | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.212); catalogued as rs763100441, COSV52195276; called by muse, mutect2, varscan2
- CARMIL2 | c.2177C>T p.S726L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV100575954; called by muse, mutect2, varscan2
- CCNI | c.116A>T p.N39I | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.262); catalogued as COSV99423213; called by muse, mutect2, varscan2
- CCNT1 | c.920C>A p.T307K | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as COSV99980497; called by muse, mutect2
- CD163 | c.2119G>A p.E707K | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV100775675; called by muse, mutect2, varscan2
- CDH15 | c.2332G>A p.D778N | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.911); catalogued as COSV99228054; called by muse, mutect2, varscan2
- CDH5 | c.1195G>A p.D399N | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100439019; called by muse, mutect2, varscan2
- CEP350 | c.3001G>A p.D1001N | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100854320; called by muse, mutect2
- CERS4 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99250443; called by muse, mutect2
- CFAP69 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 9/179 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.346); catalogued as COSV100289788, COSV100290447; called by muse, mutect2
- CLASP2 | c.1540G>C p.G514R | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100222576; called by muse, mutect2
- CLEC4M | c.94C>T p.Q32* | Nonsense Mutation (SNP) | VAF 7/97 reads (7%) | catalogued as COSV50217505; called by muse, mutect2
- CMYA5 | c.11083A>G p.S3695G | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.106); catalogued as COSV101483846, COSV71405988; called by muse, mutect2, varscan2
- CNOT4 | c.920C>G p.S307* (on ENST00000315544 / NM_001190848.1; = p.S304* on NM_013316.4) | Nonsense Mutation (SNP) | VAF 22/68 reads (32%) | catalogued as COSV100211092; called by muse, mutect2, varscan2
- COL12A1 | c.6157C>G p.Q2053E | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.726); catalogued as COSV100485418; called by muse, mutect2
- CPZ | c.926G>T p.W309L (on ENST00000360986 / NM_001014447.3; = p.W298L on NM_003652.3) | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV100248772; called by muse, mutect2, varscan2
- CSMD3 | c.6422T>G p.I2141R (on ENST00000297405 / NM_001363185.1; = p.I2037R on NM_052900.3) | Missense Mutation (SNP) | VAF 38/306 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV52151094, COSV99825390; called by muse, mutect2, varscan2
- CSMD3 | c.151T>G p.F51V | Missense Mutation (SNP) | VAF 30/316 reads (9%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.916); catalogued as COSV99825392; called by muse, mutect2
- CSTF2T | c.34G>T p.D12Y | Missense Mutation (SNP) | VAF 19/213 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100484079; called by muse, mutect2
- DAZAP1 | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99244988; called by muse, mutect2
- DHX30 | c.2395C>T p.R799W (on ENST00000445061 / NM_138615.3; = p.R760W on NM_014966.3) | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV99274721; called by muse, mutect2
- DPP3 | c.2100C>G p.F700L | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.826); catalogued as COSV100567691, COSV59150453; called by muse, mutect2, varscan2
- DST | c.2153A>G p.K718R (on ENST00000361203 / NM_001374722.1; = p.K392R on NM_001723.6) | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.053); catalogued as COSV99751327; called by muse, mutect2, varscan2
- DUS2 | c.81G>C p.M27I | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV100732413; called by muse, mutect2
- DZIP3 | c.13C>G p.P5A | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV100847646; called by muse, mutect2, varscan2
- EIF4B | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 17/173 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as rs1435209652, COSV100016649; called by muse, mutect2, varscan2
- EIF5B | c.3594C>G p.F1198L | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99176821; called by muse, mutect2
- ESD | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101099086; called by muse, mutect2, varscan2
- FAM171A1 | c.262G>T p.V88F | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100968050; called by muse, mutect2, varscan2
- FLNC | c.5015C>A p.A1672E | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.403); catalogued as COSV100367642; called by muse, mutect2
- G2E3 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV99249320; called by mutect2, varscan2
- GLYR1 | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV100424061; called by muse, mutect2
- GMPR | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV99439771; called by muse, mutect2, varscan2
- GOLGA3 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as rs778756369, COSV99202271; called by muse, mutect2
- GPR15 | c.1021C>G p.L341V | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.211); catalogued as COSV99423644; called by muse, mutect2, varscan2
- HSPA1L | c.1809G>C p.Q603H | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.797); catalogued as COSV100989481; called by muse, mutect2, varscan2
- IFRD1 | c.505C>G p.L169V | Missense Mutation (SNP) | VAF 8/241 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.268); catalogued as COSV99133630; called by muse, mutect2
- IGHV2-26 | c.257G>C p.S86T | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs782637274; called by muse, mutect2
- IGLV10-54 | c.83C>G p.S28W | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV101135418, COSV66504866; called by muse, mutect2, varscan2
- IL1R1 | c.702G>C p.E234D | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.073); catalogued as COSV99292384; called by muse, mutect2, varscan2
- IL1RAPL1 | c.428G>A p.C143Y | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100145234; called by muse, mutect2
- IMPDH2 | c.663C>G p.I221M | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.196); catalogued as COSV100454930, COSV58707440; called by muse, mutect2
- IRF5 | c.70C>A p.Q24K | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as COSV99977515; called by muse, mutect2, varscan2
- ITPR1 | c.74G>A p.G25E | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1450712967, COSV100229638; called by muse, mutect2
- KIF3C | c.25G>C p.E9Q | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as COSV99267066, COSV99267248; called by muse, mutect2
- KMT2A | c.5165C>G p.S1722C | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100628020; called by muse, mutect2, varscan2
- KNDC1 | c.5123G>A p.R1708H | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.013); catalogued as rs375653063; called by muse, mutect2, varscan2
- KRTAP10-4 | c.191C>T p.S64F | Missense Mutation (SNP) | VAF 13/160 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100551967; called by muse, mutect2
- LAMA3 | c.3565G>A p.A1189T | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs771491240, COSV58079173; called by muse, mutect2, varscan2
- LECT2 | c.252G>C p.K84N | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV99191812; called by muse, mutect2, varscan2
- LGI1 | c.1474C>G p.L492V | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101004360, COSV65058623, COSV65059234; called by muse, varscan2
- LHFPL5 | c.94C>G p.L32V | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as COSV100798929; called by muse, mutect2, varscan2
- LRRFIP2 | c.325C>T p.H109Y | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs1291501974; called by muse, mutect2
- LZTFL1 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99944732; called by muse, mutect2, varscan2
- MAP1LC3C | c.291G>A p.M97I | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as COSV100606392; called by muse, mutect2
- MASP1 | c.762A>C p.K254N | Missense Mutation (SNP) | VAF 22/272 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as COSV51459719, COSV51460052, COSV99396788; called by muse, mutect2
- MBD6 | c.278C>T p.S93L | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); catalogued as COSV100670428; called by muse, mutect2
- MEGF8 | c.6019G>T p.E2007* (on ENST00000251268 / NM_001271938.2; = p.E1940* on NM_001410.3) | Nonsense Mutation (SNP) | VAF 18/172 reads (10%) | catalogued as COSV99234516; called by muse, mutect2
- MLXIP | c.2511C>T p.F837= | Splice Region (SNP) | VAF 21/107 reads (20%) | catalogued as COSV100038464; called by muse, mutect2, varscan2
- MMP13 | c.284G>C p.R95T | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99506349, COSV99506464; called by muse, mutect2, varscan2
- MPP6 | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.034); catalogued as COSV99757198; called by muse, mutect2
- MRPL58 | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as COSV56900596; called by muse, mutect2
- MTMR8 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV100878284, COSV66396488; called by muse, mutect2
- MUC16 | c.24178G>A p.D8060N | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.125); catalogued as rs541350099, COSV101198208; called by muse, mutect2, varscan2
- MUC5B | c.6800C>T p.S2267F | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.666); catalogued as COSV101500040; called by muse, mutect2
- MYO18B | c.4672G>T p.G1558W | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100122677, COSV59127998; called by muse, mutect2
- NAE1 | c.841-1G>T p.X281_splice | Splice Site (SNP) | VAF 5/80 reads (6%) | catalogued as COSV99322951; called by muse, mutect2
- NAV2 | c.5348G>T p.G1783V (on ENST00000396087 / NM_001244963.2; = p.G1727V on NM_145117.5) | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.9); catalogued as COSV100216143; called by muse, mutect2, varscan2
- NDUFV1 | c.352G>C p.D118H | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV100295239; called by muse, mutect2, varscan2
- NFIC | c.1093C>T p.R365W | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1253555880, COSV59417574; called by muse, mutect2
- NSD3 | c.2609G>C p.R870T | Missense Mutation (SNP) | VAF 20/353 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100394932; called by muse, mutect2
- NUDT22 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99655663; called by muse, mutect2, varscan2
- OGT | c.771T>G p.N257K | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV101035172; called by muse, mutect2, varscan2
- OR13G1 | c.682G>A p.V228I | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs570053092, COSV100687072; called by muse, mutect2
- OR8I2 | c.192C>A p.S64R | Missense Mutation (SNP) | VAF 17/239 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.694); catalogued as COSV56168430; called by muse, mutect2
- PCDH17 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); catalogued as COSV100931440; called by muse, mutect2, varscan2
- PCNX1 | c.1772C>A p.P591Q | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99454115; called by muse, mutect2, varscan2
- PDE6B | c.862G>C p.D288H | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV99726931; called by muse, mutect2
- PGA5 | c.691G>A p.G231S | Missense Mutation (SNP) | VAF 62/406 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs893261892, COSV100409269; called by muse, mutect2, varscan2
- PLCD3 | c.1216C>G p.L406V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100504079; called by muse, mutect2, varscan2
- PLPPR4 | c.869G>C p.G290A | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV100926699; called by muse, mutect2, varscan2
- PLXNA2 | c.5183G>T p.S1728I | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); catalogued as COSV100885141; called by muse, mutect2, varscan2
- PPARD | c.1112A>T p.E371V | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100282942, COSV61099362; called by muse, mutect2
- PPM1B | c.1023C>G p.I341M | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.04); catalogued as COSV99175691; called by muse, mutect2, varscan2
- PRAG1 | c.230C>T p.S77L | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.036); catalogued as rs1327333698, COSV100421862; called by muse, mutect2, varscan2
- PRICKLE4 | c.418C>T p.H140Y (on ENST00000359201; = p.H180Y on NM_013397.6) | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100138628; called by muse, mutect2, varscan2
- PRPF4 | c.781G>A p.D261N (on ENST00000374198 / NM_001322267.2; = p.D262N on NM_004697.5) | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.349); catalogued as COSV100950627; called by muse, mutect2
- PSG6 | c.386G>T p.G129V | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.212); catalogued as COSV51837247, COSV99413573; called by muse, mutect2, varscan2
- PTCHD4 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.92); PolyPhen benign (0.023); catalogued as rs1484037883, COSV59799942; called by muse, mutect2, varscan2
- RASSF5 | c.1234G>C p.E412Q | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.028); catalogued as COSV55113160, COSV99662550; called by muse, mutect2, varscan2
- RELN | c.5137G>A p.E1713K | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.968); catalogued as COSV100632538; called by muse, mutect2, varscan2
- RELN | c.2936C>T p.S979L | Missense Mutation (SNP) | VAF 17/308 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.024); catalogued as COSV100632539; called by muse, mutect2
- RESF1 | c.2791C>T p.Q931* | Nonsense Mutation (SNP) | VAF 18/100 reads (18%) | catalogued as COSV100440104; called by muse, mutect2, varscan2
- RESF1 | c.3502G>C p.D1168H | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100440105, COSV57020131; called by muse, mutect2
- RHOH | c.490G>C p.E164Q | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV101110386; called by muse, mutect2, varscan2
- RIMBP3 | c.1208G>C p.R403P | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as rs1389273638; called by muse, mutect2
- RNF2 | c.367C>A p.H123N | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100835661, COSV100835748; called by muse, mutect2
- RTKN | c.1300C>G p.P434A (on ENST00000272430 / NM_001015055.2; = p.P421A on NM_033046.2) | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.953); catalogued as COSV99269334; called by muse, mutect2
- SBF2 | c.5540C>G p.S1847C | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV99813153, COSV99814788; called by muse, mutect2, varscan2
- SCGB1D4 | c.158C>A p.P53Q | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.94); catalogued as COSV100669557; called by muse, mutect2
- SCNN1G | c.1701G>C p.Q567H | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV55598372; called by muse, mutect2
- SEC16B | c.2171C>T p.S724L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV100381257; called by muse, mutect2
- SERPING1 | c.439G>A p.V147I | Missense Mutation (SNP) | VAF 32/202 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.005); catalogued as COSV99557832; called by muse, mutect2, varscan2
- SGO2 | c.372G>A p.M124I | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.41); catalogued as rs1463342309, COSV100764597; called by muse, mutect2, varscan2
- SH3BP2 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.129); catalogued as rs1308552287, COSV100696866; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SHOC1 | c.3539C>T p.P1180L | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV100597283; called by muse, mutect2, varscan2
- SLC30A6 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99249333, COSV99249435; called by muse, mutect2
- STARD13 | c.335C>T p.T112M | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778437850, COSV99715474; called by muse, mutect2, varscan2
- TLR6 | c.2368G>A p.E790K | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.051); catalogued as COSV101126235; called by muse, mutect2
- TTLL4 | c.171G>T p.K57N | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as COSV51435782; called by muse, mutect2
- TTN | c.76762G>A p.E25588K (on ENST00000591111; = p.E18164K on NM_003319.4) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | PolyPhen benign (0.124); catalogued as COSV100595031; called by muse, mutect2, varscan2
- TTN | c.74059G>A p.E24687K (on ENST00000591111; = p.E17263K on NM_003319.4) | Missense Mutation (SNP) | VAF 9/144 reads (6%) | PolyPhen probably damaging (0.994); catalogued as COSV100595033; called by muse, mutect2
- TUBA3C | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as rs778117923, COSV101262751, COSV67140249; called by muse, mutect2, varscan2
- UBR5 | c.985G>C p.D329H | Missense Mutation (SNP) | VAF 11/182 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55283852, COSV99639457; called by muse, mutect2
- UCP3 | c.400G>T p.A134S | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV100012885; called by muse, mutect2, varscan2
- UGT2B17 | c.633G>C p.R211S | Missense Mutation (SNP) | VAF 19/304 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV100497166, COSV58502103; called by muse, mutect2
- UNC13B | c.466G>C p.E156Q | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.954); catalogued as COSV101036267; called by muse, mutect2, varscan2
- USO1 | c.2281G>C p.E761Q | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.273); catalogued as COSV99362544; called by muse, mutect2
- UTP25 | c.1275C>G p.F425L | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV101504724, COSV101504755; called by muse, mutect2, varscan2
- VWA1 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100100592; called by muse, mutect2
- WBP1 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 14/185 reads (8%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.98); catalogued as COSV99270308; called by muse, mutect2
- WDHD1 | c.2408C>G p.S803C | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.199); catalogued as COSV100777536; called by muse, mutect2, varscan2
- WRN | c.3775A>G p.M1259V | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1053530158, COSV99988310; ClinVar: uncertain significance; called by muse, mutect2
- YKT6 | c.578C>G p.S193* | Nonsense Mutation (SNP) | VAF 15/302 reads (5%) | catalogued as COSV99790490; called by muse, mutect2
- ZFC3H1 | c.3916G>A p.E1306K | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as COSV101110334; called by muse, mutect2, varscan2
- ZFYVE9 | c.883G>T p.G295C | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.514); catalogued as COSV99819397; called by muse, mutect2, varscan2
- ZNF10 | c.103C>T p.Q35* | Nonsense Mutation (SNP) | VAF 17/112 reads (15%) | catalogued as rs1357754626, COSV99939851; called by muse, mutect2, varscan2
- ZNF214 | c.959A>G p.N320S | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as rs1416713090, COSV99547197; called by muse, mutect2
- ZNF281 | c.1429A>G p.K477E | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV99664015; called by muse, mutect2
- ZNF347 | c.560G>C p.S187T | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.316); catalogued as COSV100498133; called by muse, mutect2
- ZNF467 | c.1710C>G p.H570Q | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs767509714, COSV100117763, COSV57374537; called by muse, mutect2, varscan2
- ZNF878 | c.1165C>G p.H389D | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101521177; called by muse, mutect2
- ZSCAN10 | c.580G>A p.E194K (on ENST00000252463; = p.E249K on NM_032805.3) | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.815); catalogued as COSV99373832; called by muse, mutect2
- SPTBN5 | c.10626C>G p.F3542L | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- XKR3 | c.751G>T p.V251L | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.218); called by muse, mutect2
- ZSCAN18 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.51); called by muse, mutect2
- ABCB5 | c.411G>A p.K137= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV99327461; called by muse, mutect2
- AL592490.1 | c.2076T>C p.G692= | Silent (SNP) | VAF 26/108 reads (24%) | catalogued as COSV101308110; called by muse, mutect2, varscan2
- ATP2B3 | c.2517C>T p.V839= | Silent (SNP) | VAF 18/154 reads (12%) | catalogued as COSV99683088; called by muse, varscan2
- CDK15 | c.402C>T p.I134= (on ENST00000652192 / NM_001366386.2; = p.I83= on NM_139158.2) | Silent (SNP) | VAF 11/183 reads (6%) | catalogued as COSV99642732; called by muse, mutect2
- CNTNAP4 | c.666C>G p.L222= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as rs747520615, COSV100269443; called by muse, mutect2, varscan2
- COG7 | c.894C>T p.L298= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as COSV100207374; called by muse, mutect2
- COLEC10 | c.288G>A p.K96= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV100250526; called by muse, mutect2, varscan2
- CSMD3 | c.10209G>A p.Q3403= (on ENST00000297405 / NM_001363185.1; = p.Q3234= on NM_052900.3) | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV99825385; called by muse, mutect2, varscan2
- DACH1 | c.1542C>T p.S514= (on ENST00000619232 / NM_001366712.1; = p.S462= on NM_080759.6) | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV100497522; called by muse, varscan2
- DVL1 | c.84C>T p.V28= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV100491847; called by muse, mutect2, varscan2
- ELOA | c.297G>A p.K99= | Silent (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- ERLIN2 | c.492C>T p.V164= | Silent (SNP) | VAF 72/289 reads (25%) | catalogued as COSV99379436; called by muse, mutect2, varscan2
- FAT4 | c.11640C>T p.H3880= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as COSV100627275; called by muse, mutect2, varscan2
- FCGR2C | c.267C>T p.L89= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV100912515, COSV100913216; called by muse, mutect2, varscan2
- FSHR | c.1299C>T p.A433= | Silent (SNP) | VAF 18/102 reads (18%) | catalogued as COSV100436597; called by muse, mutect2, varscan2
- GPR119 | c.903C>G p.L301= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as COSV99358535; called by muse, mutect2
- GSDMD | c.615G>A p.T205= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs145648319, COSV99369586; called by muse, mutect2, varscan2
- HDAC8 | c.96C>A p.A32= | Silent (SNP) | VAF 12/100 reads (12%) | catalogued as COSV101002345; called by muse, mutect2, varscan2
- IFFO1 | c.876G>A p.L292= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV100350756; called by muse, mutect2, varscan2
- INO80D | c.1317G>A p.L439= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV101305789; called by muse, mutect2
- ITIH2 | c.2247G>A p.K749= | Silent (SNP) | VAF 22/98 reads (22%) | catalogued as rs749404489, COSV100623165; called by muse, mutect2, varscan2
- JOSD2 | c.546C>T p.G182= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV101209072; called by muse, mutect2, varscan2
- LAMA1 | c.5601G>A p.L1867= | Silent (SNP) | VAF 24/230 reads (10%) | catalogued as COSV101055076; called by muse, mutect2, varscan2
- NYAP2 | c.12C>G p.S4= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as COSV99795783; called by muse, mutect2, varscan2
- OR10J5 | c.228C>G p.V76= | Silent (SNP) | VAF 27/170 reads (16%) | catalogued as COSV100604620; called by muse, mutect2, varscan2
- PARD3B | c.2502C>G p.V834= (on ENST00000406610 / NM_001302769.2; = p.V765= on NM_057177.7) | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV100592202; called by muse, mutect2, varscan2
- PCDHB3 | c.1005C>A p.V335= | Silent (SNP) | VAF 7/93 reads (8%) | catalogued as rs782675484, COSV99164193; called by muse, mutect2
- PDE11A | c.1656C>T p.I552= | Silent (SNP) | VAF 7/86 reads (8%) | catalogued as COSV99610886; called by muse, mutect2
- PDE4B | c.172A>C p.R58= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as COSV100302290; called by muse, mutect2, varscan2
- POLA1 | c.3702C>T p.L1234= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as COSV100985026; called by muse, mutect2
- RFPL3 | c.252C>G p.V84= (on ENST00000249007 / NM_001098535.1; = p.V55= on NM_006604.2) | Silent (SNP) | VAF 12/114 reads (11%) | catalogued as rs749648064, COSV50747667, COSV99966915; called by muse, mutect2, varscan2
- SELENON | c.585C>T p.A195= | Silent (SNP) | VAF 26/121 reads (21%) | catalogued as COSV100823456; called by muse, mutect2, varscan2
- TBC1D24 | c.396C>T p.P132= | Silent (SNP) | VAF 7/73 reads (10%) | catalogued as rs371937830, COSV99564666; ClinVar: likely benign; called by muse, mutect2
- TFEB | c.396C>G p.S132= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs373529152; called by muse, mutect2, varscan2
- TPO | c.2436G>A p.A812= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as rs763673114, COSV100219764; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRIP11 | c.5919G>A p.L1973= | Silent (SNP) | VAF 13/119 reads (11%) | catalogued as COSV99970336; called by muse, mutect2, varscan2
- UBN1 | c.1848G>A p.Q616= | Silent (SNP) | VAF 24/299 reads (8%) | catalogued as COSV99277457; called by muse, mutect2
- UNC5C | c.2490G>A p.A830= | Silent (SNP) | VAF 24/238 reads (10%) | catalogued as rs762675647, COSV71658933; called by muse, mutect2, varscan2
- ZIM3 | c.175T>C p.L59= | Silent (SNP) | VAF 9/89 reads (10%) | catalogued as rs779699970, COSV99517656; called by muse, mutect2, varscan2
- ZNF213 | c.198C>T p.L66= | Silent (SNP) | VAF 9/120 reads (8%) | catalogued as rs777946424, COSV101205930; called by muse, mutect2
- ZNF513 | c.570C>T p.L190= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as rs375241916; called by muse, mutect2, varscan2
- CFAP47 | c.5536-614T>A | Intron (SNP) | VAF 7/65 reads (11%) | catalogued as COSV100544954; called by muse, mutect2
- IDH3B | c.*285C>T | 3'UTR (SNP) | VAF 4/33 reads (12%) | catalogued as COSV100249942; called by muse, mutect2
- NDUFV1 | chr11:67604769 G>A | 5'Flank (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2, varscan2
